Somatic mutation profile of tumor specimen 0DJPCW from CCDI case PBBXLM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Mucoepidermoid carcinoma; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 17.2 years (6,270 days).
Specimen 0DJPCW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 286cf5fc-9afd-4da2-9cd8-34ca35c20c98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJPCQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab205942-c63e-4043-88bb-a1ea817e2b09

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAF1 | c.1653G>C p.E551D | Missense Mutation (SNP) | VAF 137/632 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV65641108; called by muse, mutect2, varscan2
- FLI1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 262/1010 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs759402782; called by muse, mutect2, varscan2
- EIF3B | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 101/794 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- GEMIN2 | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 234/926 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- POLR2B | c.2903A>G p.N968S | Missense Mutation (SNP) | VAF 222/1081 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NR4A1 | c.327C>T p.Y109= | Silent (SNP) | VAF 103/339 reads (30%) | catalogued as rs1019740553; called by muse, mutect2, varscan2
- CFH | c.619+46A>T | Intron (SNP) | VAF 15/349 reads (4%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- TCHHL1 | chr1:152079715 C>G | 3'Flank (SNP) | VAF 195/764 reads (26%) | called by muse, mutect2, varscan2
